Gene-level copy-number profile of tumor specimen ALCH-B2UF-TTP1-A from ALCHEMIST case ALCH-B2UF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.9 years (26,609 days).
Specimen ALCH-B2UF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eaef34c2-0e0c-4470-bbc4-156686117cca.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2UF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/327767e3-de19-48db-934b-7dba2c10b0d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 6,988; copy number 2: 49,575; copy number 3: 2,286; copy number 4: 9; copy number 7: 1; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:4,775,615–4,794,397, 3 genes: AP5Z1, MIR4656, AC092610.1.
- chr7:98,211,439–98,215,457, 1 gene (within-gene range 0–2): BHLHA15.
- chr13:19,736,975–19,737,254, 1 gene (within-gene range 0–2): RN7SL166P.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:1,088,226–1,113,399, 3 genes: C1QTNF8, AL031713.1, AL031598.1.
- chr16:46,884,362–46,931,289, 1 gene: GPT2.
- chr19:1,905,372–1,926,013, 2 genes: SCAMP4, ADAT3.
- chr19:56,176,008–56,185,775, 1 gene: GALP.
- chr20:64,034,344–64,039,962, 1 gene (within-gene range 0–2): C20orf204.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:83,220,527–83,240,804, 2 genes, copy number 9: AC139099.1, RPL23AP87.
- chr19:42,387,019–42,390,297, 1 gene, copy number 7: CNFN.

Autosomal genes at a single copy (total copy number 1): 4,168. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
